Somatic mutation profile of tumor specimen TCGA-61-1738-01A (aliquot TCGA-61-1738-01A-01W-0639-09) from TCGA case TCGA-61-1738, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 60.1 years (21,965 days).
Specimen TCGA-61-1738-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5eb28830-7270-42c4-b7b1-297524013aad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-1738-11A (Solid Tissue Normal), aliquot TCGA-61-1738-11A-01W-0639-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b5db07f-7a41-43cf-870c-34bbe62ccb22

The open-access MAF lists 65 somatic variants for this specimen: 52 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 12, Nonsense Mutation 5, Frame Shift Del 2, Splice Region 1, Frame Shift Ins 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.344G>T p.R115L | Missense Mutation (SNP) | VAF 179/284 reads (63%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.177); catalogued as rs200018596, CM1312620, COSV55890007, COSV55898949, COSV55991501; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 65/74 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAM17 | c.851T>G p.I284S | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60398565; called by muse, mutect2, varscan2
- AK1 | c.544G>C p.V182L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.27); catalogued as COSV56345050; called by muse, mutect2, varscan2
- ANK2 | c.3184C>T p.R1062C | Missense Mutation (SNP) | VAF 99/239 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147934418; called by muse, mutect2, varscan2
- ARHGAP35 | c.1102A>T p.K368* | Nonsense Mutation (SNP) | VAF 119/201 reads (59%) | catalogued as COSV68330803, COSV68330838; called by muse, mutect2, varscan2
- ARMC3 | c.2092G>C p.E698Q | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.462); catalogued as COSV99957839; called by muse, mutect2
- BRPF3 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV60207101; called by muse, mutect2, varscan2
- CEP164 | c.1629T>A p.H543Q | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.01); catalogued as COSV54040691; called by muse, mutect2, varscan2
- CLASP1 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 227/567 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as rs1265888562; called by muse, mutect2, varscan2
- DPYD | c.486A>G p.V162= | Splice Region (SNP) | VAF 219/479 reads (46%) | catalogued as COSV64596517; called by muse, mutect2, varscan2
- EGLN2 | c.598G>C p.A200P | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV100393696, COSV100393839; called by muse, mutect2
- FTSJ3 | c.2401G>A p.V801I | Missense Mutation (SNP) | VAF 276/850 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.766); catalogued as rs762982336, COSV63790031; called by muse, mutect2, varscan2
- GALK2 | c.1021C>T p.R341* | Nonsense Mutation (SNP) | VAF 57/75 reads (76%) | catalogued as rs144322038; called by muse, mutect2, varscan2
- HNRNPH1 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.408); catalogued as COSV100270499; called by muse, mutect2
- HR | c.3165C>G p.H1055Q | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57191840; called by muse, mutect2, varscan2
- HSPA5 | c.1842A>T p.E614D | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.042); catalogued as COSV52335156; called by muse, mutect2, varscan2
- IRAG2 | c.3977C>T p.S1326F (on ENST00000636465; = p.S371F on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/134 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1266497350, COSV100209234, COSV57230194; called by muse, mutect2
- KIAA1217 | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs751665913, COSV100286472; called by muse, mutect2
- KLF7 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.637); catalogued as rs1372858612, COSV58746065; called by muse, mutect2
- KYNU | c.748G>C p.D250H | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51582727, COSV99932611; called by muse, mutect2, varscan2
- LEPROT | c.269G>C p.R90P | Missense Mutation (SNP) | VAF 70/812 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100756535, COSV60746319; called by muse, mutect2
- LRP4 | c.3685G>A p.D1229N | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760528582, COSV66135527; called by muse, mutect2, varscan2
- MAP3K1 | c.2128T>C p.C710R | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV68123340; called by muse, mutect2, varscan2
- MTHFD2 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs747820994, COSV51201346; called by muse, mutect2, varscan2
- MUC17 | c.4583G>C p.S1528T | Missense Mutation (SNP) | VAF 67/485 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV60287214; called by muse, mutect2, varscan2
- NAALAD2 | c.1927G>A p.V643I | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV58960583; called by muse, mutect2, varscan2
- OBSL1 | c.2077G>A p.A693T | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV54718031; called by muse, mutect2, varscan2
- PCDHA2 | c.310A>T p.I104F | Missense Mutation (SNP) | VAF 71/165 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.336); catalogued as COSV65366649; called by muse, mutect2, varscan2
- PCDHB10 | c.1543G>A p.A515T | Missense Mutation (SNP) | VAF 90/199 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV53378234; called by muse, mutect2, varscan2
- PPP1R3B | c.728T>A p.M243K | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV60099414; called by muse, mutect2, varscan2
- PRSS35 | c.652G>T p.G218C | Missense Mutation (SNP) | VAF 91/213 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.319); catalogued as COSV63800492; called by muse, varscan2
- RUBCN | c.830dup p.V278Sfs*16 | Frame Shift Ins (INS) | VAF 9/61 reads (15%) | catalogued as rs745498865; called by mutect2, varscan2
- RYR2 | c.812C>G p.A271G | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as COSV100769550; called by muse, mutect2
- SCN8A | c.724G>A p.G242S | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); catalogued as COSV61980747; called by muse, mutect2, varscan2
- SMG1 | c.5242T>G p.C1748G | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV101245692; called by muse, mutect2, varscan2
- SMTNL1 | c.1331G>A p.R444H (on ENST00000399154; = p.R481H on NM_001105565.2) | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.554); catalogued as rs202111094; called by muse, mutect2, varscan2
- SORCS1 | c.1606T>A p.Y536N | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53862438; called by muse, mutect2, varscan2
- SRP68 | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 13/267 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.246); catalogued as COSV100326061; called by muse, mutect2
- STAG3 | c.3047C>T p.S1016F | Missense Mutation (SNP) | VAF 154/545 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57930050; called by mutect2, varscan2
- TNFAIP8 | c.277C>T p.Q93* | Nonsense Mutation (SNP) | VAF 13/134 reads (10%) | catalogued as COSV99174257; called by muse, mutect2
- TSPEAR | c.130G>T p.A44S | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV59957782, COSV59960387; called by muse, mutect2, varscan2
- TTN | c.67352C>A p.S22451* (on ENST00000591111; = p.S15027* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 77/161 reads (48%) | catalogued as COSV100600378, COSV60020877; called by muse, mutect2, varscan2
- UBR5 | c.8059G>A p.V2687M | Missense Mutation (SNP) | VAF 76/141 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV55285641; called by muse, mutect2, varscan2
- ZEB2 | c.2551T>C p.S851P | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.193); catalogued as COSV100355745; called by muse, mutect2
- ZGRF1 | c.1677G>A p.W559* | Nonsense Mutation (SNP) | VAF 133/267 reads (50%) | catalogued as COSV52199029; called by muse, mutect2, varscan2
- ZNF462 | c.7209C>A p.D2403E | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV52936817; called by muse, mutect2, varscan2
- BRD1 | c.1170del p.P391Qfs*8 | Frame Shift Del (DEL) | VAF 62/83 reads (75%) | called by mutect2, pindel, varscan2
- FCGBP | c.2741G>C p.S914T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- PPIAL4A | c.187C>G p.Q63E | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.211); called by muse, mutect2
- SMC3 | c.1465del p.D489Ifs*18 | Frame Shift Del (DEL) | VAF 54/139 reads (39%) | called by mutect2, pindel, varscan2
- WDFY3 | c.9318_9335del p.M3107_E3112del | In Frame Del (DEL) | VAF 20/76 reads (26%) | called by mutect2, pindel, varscan2
- ADIPOR1 | c.834C>T p.G278= | Silent (SNP) | VAF 58/147 reads (39%) | catalogued as rs772084276, COSV61851430; called by muse, mutect2, varscan2
- CFHR1 | c.714G>A p.Q238= | Silent (SNP) | VAF 76/183 reads (42%) | catalogued as COSV57627002; called by muse, mutect2, varscan2
- KPNA5 | c.63C>T p.A21= | Silent (SNP) | VAF 110/276 reads (40%) | catalogued as COSV62652260; called by muse, mutect2, varscan2
- KRT76 | c.459G>A p.G153= | Silent (SNP) | VAF 59/98 reads (60%) | catalogued as COSV60120056; called by muse, mutect2, varscan2
- NCK2 | c.84G>T p.R28= | Silent (SNP) | VAF 42/90 reads (47%) | catalogued as COSV51890974; called by muse, mutect2, varscan2
- OASL | c.534C>T p.I178= | Silent (SNP) | VAF 60/210 reads (29%) | catalogued as COSV57478103, COSV99984478; called by muse, mutect2, varscan2
- P2RX1 | c.459C>T p.N153= | Silent (SNP) | VAF 13/17 reads (76%) | catalogued as rs778602969, COSV56653740; called by muse, mutect2, varscan2
- PLCB3 | c.2595C>T p.H865= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs1192707997, COSV54188112; called by muse, mutect2
- PTGR2 | c.471A>T p.T157= | Silent (SNP) | VAF 16/136 reads (12%) | catalogued as COSV50865675; called by muse, mutect2, varscan2
- SGSM2 | c.1914C>T p.I638= (on ENST00000426855 / NM_001098509.2; = p.I683= on NM_014853.3) | Silent (SNP) | VAF 13/13 reads (100%) | catalogued as rs1281948657, COSV52157636; called by muse, mutect2, varscan2
- SLC23A1 | c.597C>T p.V199= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as rs200969580, COSV62296378; called by muse, mutect2, varscan2
- TSHZ2 | c.1953G>A p.L651= | Silent (SNP) | VAF 14/252 reads (6%) | catalogued as COSV61592468; called by muse, mutect2
- GABRG2 | c.1248+256A>C | Intron (SNP) | VAF 5/34 reads (15%) | catalogued as COSV62717658; called by muse, mutect2, varscan2
